Somatic mutation profile of tumor specimen TCGA-ER-A2NE-06A (aliquot TCGA-ER-A2NE-06A-21D-A196-08) from TCGA case TCGA-ER-A2NE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.6 years (14,826 days).
Specimen TCGA-ER-A2NE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba4ef5c-84fb-48b8-9231-64bcc8d7240f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2NE-10A (Blood Derived Normal), aliquot TCGA-ER-A2NE-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b63ce2-8273-4abb-93f5-3f6c2aafd78a

The open-access MAF lists 154 somatic variants for this specimen: 101 protein-altering or splice-affecting, 43 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 43, Intron 3, Nonsense Mutation 3, RNA 3, 3'Flank 2, Frame Shift Del 2, Splice Region 2, Splice Site 2, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 62/142 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, varscan2
- ABCC1 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60692579; called by muse, mutect2, varscan2
- ABL1 | c.2290C>G p.R764G | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs773883545, COSV59338988; called by muse, mutect2, varscan2
- ADAMDEC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs868610362, COSV56474181; called by muse, mutect2, varscan2
- ADCY10 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV63244093; called by muse, mutect2, varscan2
- ADGRE3 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53734143; called by muse, mutect2, varscan2
- AKAP6 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55229404; called by muse, mutect2, varscan2
- ANKRD11 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56369692; called by muse, mutect2, varscan2
- APBB2 | c.854C>A p.S285* (on ENST00000295974 / NM_001166050.2; = p.S286* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as COSV55960578; called by muse, mutect2, varscan2
- ATP13A5 | c.3619G>A p.G1207S | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV53232970; called by muse, mutect2, varscan2
- BANK1 | c.91A>T p.M31L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59848655; called by mutect2, varscan2
- BMP10 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV54896655; called by muse, mutect2, varscan2
- BMX | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 124/138 reads (90%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); catalogued as COSV59593122; called by muse, mutect2, varscan2
- C4B | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV70313333; called by muse, mutect2, varscan2
- CCDC144A | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs750175196, COSV60701277; called by mutect2, varscan2
- CDHR4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58526861; called by muse, mutect2, varscan2
- CES1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62085963; called by muse, mutect2, varscan2
- CFAP221 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.487); catalogued as rs757372415, COSV54661659; called by muse, mutect2, varscan2
- CLCN1 | c.1065G>A p.G355= | Splice Region (SNP) | VAF 31/72 reads (43%) | catalogued as rs1455434689, COSV58373800; called by muse, mutect2, varscan2
- COL11A2 | c.2687C>T p.P896L (on ENST00000341947 / NM_080680.3; = p.P789L on NM_080679.2) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs150065075; called by muse, mutect2, varscan2
- CPPED1 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55500734; called by muse, mutect2, varscan2
- CTSV | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52345603; called by muse, mutect2, varscan2
- CYP8B1 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV60227454; called by muse, mutect2, varscan2
- DNAAF5 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs1206211230, COSV52420465; called by muse, mutect2, varscan2
- ECM2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV60742617; called by muse, mutect2, varscan2
- EIF3D | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV53405164; called by muse, mutect2, varscan2
- EPHA10 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60405183; called by muse, mutect2, varscan2
- EPHA4 | c.1851C>G p.D617E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV56042428, COSV56042499; called by muse, mutect2, varscan2
- EPHB3 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV57808713; called by muse, varscan2
- ERICH3 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs267598716, COSV58616091; called by muse, mutect2, varscan2
- F13A1 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs577966272, COSV53565772; called by muse, mutect2, varscan2
- FAM234B | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.092); catalogued as COSV52196912; called by muse, mutect2, varscan2
- FANCB | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60761417; called by muse, mutect2, varscan2
- FCRL3 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63844375; called by muse, mutect2, varscan2
- FLNC | c.5458G>A p.G1820S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs763930207, COSV57963007; called by muse, mutect2, varscan2
- FNDC5 | c.423G>C p.M141I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs757750681, COSV65106034; called by muse, mutect2, varscan2
- FSIP2 | c.18928G>A p.E6310K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1437197254, COSV58077790; called by muse, mutect2, varscan2
- FYB2 | c.1943G>C p.R648T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs1429512044, COSV100599360, COSV58588460; called by muse, mutect2, varscan2
- GBA3 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV72438608; called by muse, mutect2, varscan2
- GDA | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52996907, COSV99429615; called by muse, mutect2, varscan2
- GHR | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50126231; called by muse, mutect2, varscan2
- GLI2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58049577; called by muse, mutect2, varscan2
- HPS3 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV52833265; called by mutect2, varscan2
- KCNK1 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV64036181; called by muse, mutect2, varscan2
- KIF13B | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73054666; called by muse, mutect2, varscan2
- KIF3B | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65229076; called by muse, mutect2, varscan2
- KMT2D | c.6257A>G p.K2086R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780048854, COSV56478582; called by muse, mutect2, varscan2
- LRRC52 | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54233416; called by muse, mutect2, varscan2
- LRTM1 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs533883378, COSV55516265; called by muse, mutect2, varscan2
- LYN | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV70206323; called by muse, mutect2, varscan2
- MESD | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs762303952, COSV55725542; called by muse, mutect2, varscan2
- MIIP | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT tolerated (0.45); PolyPhen benign (0.178); catalogued as COSV52428565; called by muse, mutect2, varscan2
- MUC16 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs763691043, COSV67448892; called by muse, mutect2, varscan2
- MYH7 | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as COSV62522969; called by muse, mutect2, varscan2
- NDFIP2 | c.909C>T p.G303= | Splice Region (SNP) | VAF 77/208 reads (37%) | catalogued as COSV54529841; called by muse, mutect2, varscan2
- NLRP11 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100789704, COSV64088393; called by muse, mutect2, varscan2
- NLRP7 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs867452150, COSV60173656; called by muse, mutect2, varscan2
- NOX4 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV54462592; called by muse, mutect2, varscan2
- NPC1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV52582857; called by muse, mutect2, varscan2
- OR13C3 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66166212; called by muse, mutect2, varscan2
- OR4N2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV60054383; called by muse, mutect2, varscan2
- OTUD7A | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191906, COSV100192479; called by muse, mutect2
- PCDHA4 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); catalogued as rs781790264, COSV63545243; called by muse, mutect2, varscan2
- PMFBP1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV52830703; called by muse, mutect2, varscan2
- PTPRT | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.712); catalogued as COSV62011906; called by mutect2, varscan2
- RHOV | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as rs1186510308, COSV55027816; called by muse, mutect2, varscan2
- ROBO3 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101184966, COSV67302513; called by muse, mutect2, varscan2
- RP1L1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 83/92 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs762473280, COSV66754699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.5231G>A p.S1744N (on ENST00000333535 / NM_198056.3; = p.S1743N on NM_000335.5) | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.22); catalogued as COSV61138379; called by muse, mutect2, varscan2
- SDK2 | c.5689G>A p.D1897N | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV66194754; called by muse, mutect2, varscan2
- SFI1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | catalogued as rs972358795, COSV66292568; called by muse, mutect2, varscan2
- SGSM3 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs1473849853, COSV50654633; called by muse, mutect2, varscan2
- SLAMF8 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56989658; called by muse, mutect2, varscan2
- SLC13A4 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62462564; called by muse, mutect2, varscan2
- SLC15A2 | c.6T>A p.N2K | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV55200365; called by muse, mutect2
- SLC8A1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752998555, COSV60493942, COSV60498021; called by muse, mutect2, varscan2
- SLC9A4 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54831814; called by muse, mutect2, varscan2
- SND1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV61247726; called by muse, mutect2, varscan2
- SNTB2 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as COSV60351494; called by muse, mutect2, varscan2
- ST6GAL2 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 105/193 reads (54%) | PolyPhen benign (0.014); catalogued as COSV64528315; called by muse, mutect2, varscan2
- ST8SIA2 | c.176T>G p.I59R | Missense Mutation (SNP) | VAF 8/149 reads (5%) | PolyPhen benign (0.031); catalogued as COSV51572352; called by muse, mutect2
- SUGP1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1284644586, COSV53237853; called by muse, mutect2, varscan2
- TCN2 | c.428-1G>A p.X143_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53192789, COSV99308359; called by muse, mutect2, varscan2
- TICAM1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV50238701; called by muse, mutect2, varscan2
- TIGAR | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs766748069, COSV51629564; called by muse, mutect2, varscan2
- TMEM108 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV58880922; called by muse, mutect2, varscan2
- TMPRSS11E | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59520817, COSV59521035; called by muse, mutect2, varscan2
- TRIOBP | c.4175C>T p.S1392F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV60383362; called by muse, mutect2, varscan2
- TRPC4 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV59014462; called by muse, mutect2, varscan2
- TRPM6 | c.1841G>T p.W614L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62520612; called by muse, mutect2, varscan2
- TTN | c.68225C>T p.S22742L (on ENST00000591111; = p.S15318L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | PolyPhen possibly damaging (0.482); catalogued as rs368415251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.48155C>T p.P16052L (on ENST00000591111; = p.P8628L on NM_003319.4) | Missense Mutation (SNP) | VAF 117/269 reads (43%) | PolyPhen probably damaging (0.951); catalogued as rs1176166730, COSV60289197; called by muse, mutect2, varscan2
- UBQLN1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57409105; called by muse, mutect2, varscan2
- UGT3A1 | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57102091; called by muse, mutect2, varscan2
- USP37 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1202107335, COSV51446692; called by muse, mutect2, varscan2
- ZFHX4 | c.8516C>T p.P2839L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV51490615; called by muse, mutect2, varscan2
- ZNF714 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV52515019; called by muse, mutect2, varscan2
- ANAPC4 | c.12del p.P5Rfs*64 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- DIS3L | c.1082del p.N361Mfs*54 (on ENST00000319212 / NM_001143688.3; = p.N278Mfs*54 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/131 reads (40%) | called by mutect2, pindel, varscan2
- GABRB3 | c.436_437dup p.D146Efs*18 | Frame Shift Ins (INS) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- MIGA2 | c.97-17_108del p.X33_splice | Splice Site (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel
- AKR1D1 | c.207G>A p.R69= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1308042084, COSV54336847; called by muse, mutect2, varscan2
- ART4 | c.171C>T p.F57= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs201915266; called by muse, mutect2, varscan2
- ASTN1 | c.2082G>A p.V694= | Silent (SNP) | VAF 42/54 reads (78%) | catalogued as COSV56081827; called by muse, mutect2, varscan2
- B4GALNT3 | c.1473C>T p.S491= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV56752644; called by muse, mutect2, varscan2
- BMP15 | c.876C>T p.S292= | Silent (SNP) | VAF 50/55 reads (91%) | catalogued as COSV53141802, COSV99399370; called by muse, mutect2, varscan2
- C1QTNF9 | c.774C>T p.F258= | Silent (SNP) | VAF 62/99 reads (63%) | catalogued as COSV59657939, COSV59658280; called by muse, mutect2, varscan2
- CDH26 | c.1335C>T p.S445= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs773935366, COSV54843160; called by muse, mutect2, varscan2
- CFAP54 | c.7546C>T p.L2516= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV61574715; called by muse, mutect2, varscan2
- CFHR2 | c.780G>A p.G260= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as rs1415011030, COSV66380924; called by muse, mutect2, varscan2
- CPZ | c.1896C>T p.P632= (on ENST00000360986 / NM_001014447.3; = p.P621= on NM_003652.3) | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV59925310; called by muse, mutect2, varscan2
- DCHS1 | c.5529G>A p.V1843= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100202022; called by muse, mutect2, varscan2
- DSC1 | c.1779G>A p.L593= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV57150573; called by muse, mutect2, varscan2
- FLRT2 | c.1923C>T p.I641= | Silent (SNP) | VAF 155/367 reads (42%) | catalogued as rs1288944006, COSV58148656; called by muse, mutect2, varscan2
- GBF1 | c.1335C>T p.A445= (on ENST00000369983 / NM_001377137.1; = p.A444= on NM_004193.3) | Silent (SNP) | VAF 70/84 reads (83%) | catalogued as rs1398336832, COSV64148321; called by muse, mutect2, varscan2
- GBGT1 | c.810C>T p.A270= | Silent (SNP) | VAF 83/142 reads (58%) | catalogued as COSV64410553; called by muse, mutect2, varscan2
- GP2 | c.1041G>A p.G347= (on ENST00000381362 / NM_001007240.3; = p.G344= on NM_001502.4) | Silent (SNP) | VAF 105/217 reads (48%) | catalogued as rs1335947800, COSV56896034, COSV56896172, COSV56896346; called by muse, mutect2, varscan2
- HSD17B11 | c.816C>T p.I272= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs748654789, COSV64155154; called by muse, mutect2, varscan2
- KIF3C | c.1695G>A p.E565= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV53101349; called by muse, mutect2
- LIPE | c.501G>A p.R167= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV54923311; called by muse, mutect2, varscan2
- LRIF1 | c.1266C>T p.S422= | Silent (SNP) | VAF 88/187 reads (47%) | catalogued as COSV63898297; called by muse, mutect2, varscan2
- MFGE8 | c.516C>T p.I172= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV51557541; called by muse, mutect2, varscan2
- NOBOX | c.867G>A p.K289= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV56197181; called by muse, mutect2, varscan2
- NPFFR2 | c.1494G>A p.R498= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs1482313325, COSV58153451; called by muse, mutect2, varscan2
- NRXN3 | c.1719C>T p.I573= (on ENST00000335750 / NM_001330195.2; = p.I200= on NM_004796.6) | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as COSV59797621; called by muse, mutect2, varscan2
- OR4A5 | c.750C>T p.P250= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1353064774, COSV100157020, COSV60524290; called by muse, mutect2, varscan2
- OR4S2 | c.621G>A p.G207= | Silent (SNP) | VAF 69/80 reads (86%) | catalogued as COSV56748061; called by muse, mutect2, varscan2
- OR51L1 | c.801G>A p.G267= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV58625538; called by muse, mutect2, varscan2
- OR51T1 | c.969G>A p.R323= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100434396; called by muse, mutect2, varscan2
- PEAR1 | c.30C>T p.L10= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV52775449; called by muse, mutect2, varscan2
- PMP2 | c.252C>T p.I84= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs149339630, COSV56267807; called by muse, mutect2, varscan2
- PRR27 | c.186C>T p.Y62= | Silent (SNP) | VAF 79/171 reads (46%) | catalogued as rs372651799, COSV60641356; called by muse, mutect2, varscan2
- PSMD1 | c.2805C>T p.I935= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58078474; called by muse, mutect2, varscan2
- RIPK4 | c.1383C>T p.A461= (on ENST00000352483; = p.A413= on NM_020639.3) | Silent (SNP) | VAF 109/229 reads (48%) | catalogued as COSV60190429; called by muse, mutect2, varscan2
- ROR2 | c.1101C>T p.N367= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs765839790, COSV65217912, COSV65222800; called by muse, mutect2, varscan2
- RUBCN | c.1138C>T p.L380= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV56372757; called by muse, mutect2, varscan2
- SCAP | c.1389C>T p.P463= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs762408827, COSV55565116; called by muse, mutect2, varscan2
- SLC2A8 | c.1197G>A p.E399= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV64894984; called by muse, mutect2, varscan2
- SLC5A6 | c.783C>T p.F261= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs763248415, COSV60160252; called by muse, mutect2, varscan2
- TFPI2 | c.636G>A p.L212= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV55991694; called by muse, mutect2, varscan2
- TMEM176B | c.480C>T p.I160= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs148000953; called by muse, mutect2, varscan2
- TTN | c.10044C>T p.I3348= (on ENST00000591111; = p.I3302= on NM_003319.4) | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as rs1553983924, COSV59960254; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.333C>T p.S111= | Silent (SNP) | VAF 52/92 reads (57%) | catalogued as COSV54728602; called by muse, mutect2, varscan2
- ZNF544 | c.1839C>T p.F613= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV54138141; called by muse, mutect2, varscan2
- AC024940.1 | n.3103C>T | RNA (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500709 del A | 5'Flank (DEL) | VAF 36/65 reads (55%) | called by mutect2, pindel, varscan2
- FABP5P3 | chr7:152446828 C>T | 3'Flank (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- MIR9-1 | chr1:156416790 A>T | 3'Flank (SNP) | VAF 66/160 reads (41%) | catalogued as COSV59485312; called by muse, mutect2, varscan2
- PRR12 | c.52-371C>T | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101330664; called by mutect2, varscan2
- PRR12 | c.52-368del | Intron (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- RNA5-8SP2 | n.93G>A | RNA (SNP) | VAF 13/31 reads (42%) | catalogued as rs483066; called by muse, mutect2, varscan2
- SERPINA13P | n.1120C>T | RNA (SNP) | VAF 15/19 reads (79%) | catalogued as rs759346230; called by muse, mutect2, varscan2
- TTN | c.10361-4565C>T | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100588697, COSV100611926; called by muse, mutect2, varscan2
- ZNF99 | c.*716C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as COSV68054629, COSV68055914; called by muse, mutect2, varscan2
